CCDI case PBBJJT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8cee15d9-1f4a-4139-9102-ebf955baaa35

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.4 years (2,719 days).

Biospecimens (3 samples)
- Sample 0D9XFD: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9XFE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0D9XFF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
